Gene-level copy-number profile of specimen HCM-BROD-0229-C25-85A from HCMI case HCM-BROD-0229-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Age at diagnosis: 60.6 years (22,116 days).
Specimen HCM-BROD-0229-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bd9df30c-232d-48bb-b3fd-903ac5f97f34.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0229-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/68793fa7-1c67-46f3-a9df-eaae49e20989

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 8,221; copy number 2: 45,392; copy number 3: 4,496; copy number 4: 45; copy number 5: 181; copy number 6: 24; copy number 7: 24; copy number 124: 7.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:129,771,596–129,975,329, 2 genes: LINC02465, EEF1GP8.
- chr5:21,493,436–21,494,596, 1 gene (within-gene range 0–1): AC138951.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 236 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:127,289,817–127,742,951, 7 genes, copy number 124: CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC.
- chr12:63,844,700–64,162,217, 1 gene, copy number 5 (within-gene range 3–5): SRGAP1.
- chr12:64,032,412–71,586,310, 164 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:72,087,266–72,728,844, 5 genes, copy number 6 (within-gene range 3–6): TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1.
- chr12:73,648,666–74,402,600, 11 genes, copy number 6–7: AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3.
- chr17:15,436,015–16,391,882, 47 genes, copy number 5–7 (within-gene range 3–7): CDRT4, TVP23C-CDRT4, RPL9P2, TVP23C, PPIAP53, AC005838.2, CDRT1, AC005324.2, SNORA74, AC005838.1, TRIM16, AC005324.4, ZNF29P, ZNF286A, AC005324.3, UBE2SP1, TBC1D26, TBC1D26-AS1, AC005324.5, AC005324.1, CDRT15P2, ZSWIM5P1, RNA5SP436, IL6STP1, MEIS3P1, AC015922.2, AC015922.3, AC015922.1, LINC02087, SPECC1P1, ADORA2B, ZSWIM7, TTC19, AC002553.2, NCOR1, AC002553.1, RPLP1P11, RPL22P21, RNU6-314P, RNU6-862P, RN7SL442P, PIGL, MIR1288, CENPV, UBB, AC093484.3, FTLP12.
- chr18:45,034–46,047, 1 gene, copy number 6: AP001005.1.

Autosomal genes at a single copy (total copy number 1): 8,108. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
